Somatic mutation profile of tumor specimen MMRF_1500_2_BM_CD138pos (aliquot MMRF_1500_2_BM_CD138pos_T1_KHS5U_L14852) from MMRF case MMRF_1500, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.4 years (22,054 days).
Specimen MMRF_1500_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6313096-1f25-4934-8c41-2e6af1b4d15f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1500_2_PB_WBC (Blood Derived Normal), aliquot MMRF_1500_2_PB_WBC_C3_KHS5U_L14854; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/83fcbdd6-dc95-4acc-b2e1-57d173954449

The open-access MAF lists 225 somatic variants for this specimen: 100 protein-altering or splice-affecting, 27 silent, 98 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, 3'UTR 58, Silent 27, Intron 24, 3'Flank 7, 5'UTR 6, Nonsense Mutation 5, Splice Region 3, Splice Site 3, 5'Flank 3, Frame Shift Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 20/92 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.2594G>A p.R865Q (on ENST00000614293; = p.R835Q on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/305 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs201546770, COSV99688678; called by muse, mutect2, varscan2
- ARHGAP19 | c.1219C>T p.R407* | Nonsense Mutation (SNP) | VAF 52/239 reads (22%) | catalogued as rs751754099; called by muse, mutect2, varscan2
- ARL13A | c.74C>G p.P25R | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV71448295; called by muse, mutect2, varscan2
- ASTN1 | c.3754G>T p.G1252W | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.299); catalogued as COSV62496202; called by muse, mutect2, varscan2
- CEP70 | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.046); catalogued as COSV53875159; called by muse, mutect2, varscan2
- CHD6 | c.3477C>G p.I1159M | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58554103; called by muse, mutect2, varscan2
- CLEC4C | c.271C>A p.Q91K | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV63582865; called by muse, mutect2, varscan2
- DDA1 | c.137-2A>C p.X46_splice | Splice Site (SNP) | VAF 9/106 reads (8%) | catalogued as COSV63290037; called by muse, mutect2
- DNAAF3 | c.164T>C p.V55A (on ENST00000524407 / NM_001256715.2; = p.V102A on NM_178837.4) | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT tolerated (1); PolyPhen possibly damaging (0.722); catalogued as rs761210447; called by muse, mutect2, varscan2
- FAM83G | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370774339; called by muse, mutect2, varscan2
- FGD2 | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 44/288 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.214); catalogued as rs777052919; called by muse, mutect2, varscan2
- GALNTL6 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 47/221 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs146548110, COSV72490733, COSV72495008; called by muse, mutect2, varscan2
- IGHV3-23 | c.217A>G p.S73G | Missense Mutation (SNP) | VAF 134/1134 reads (12%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs571928197; called by muse, varscan2
- IPCEF1 | c.743T>C p.V248A | Missense Mutation (SNP) | VAF 72/333 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1276311719; called by muse, mutect2, varscan2
- ITIH6 | c.1207G>A p.G403S | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.376); catalogued as rs747260784, COSV54492091; called by muse, mutect2, varscan2
- ITM2C | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs143044408; called by muse, mutect2, varscan2
- MS4A7 | c.51G>T p.K17N | Missense Mutation (SNP) | VAF 54/433 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.012); catalogued as COSV55728606; called by muse, varscan2
- OR51E1 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 50/293 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.54); catalogued as rs575981363, COSV67809895; called by muse, mutect2, varscan2
- OR5H14 | c.634G>C p.G212R | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs1391620357, COSV101454216; called by muse, mutect2
- PIWIL3 | c.854G>A p.S285N | Missense Mutation (SNP) | VAF 52/330 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs1178101343; called by muse, mutect2, varscan2
- POU3F3 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as COSV63721124; called by muse, mutect2
- QSER1 | c.854C>T p.T285I (on ENST00000399302; = p.T414I on NM_001076786.3) | Missense Mutation (SNP) | VAF 78/355 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs79552406, COSV67901350; called by muse, mutect2, varscan2
- RAPGEF2 | c.2130A>C p.Q710H | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1352224709; called by muse, mutect2, varscan2
- RGS22 | c.3109C>T p.R1037C | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs370385204; called by muse, mutect2, varscan2
- RPRD2 | c.1861A>G p.T621A | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as rs1460606711, COSV100955385; called by muse, mutect2, varscan2
- SLC23A3 | c.1167+5G>A | Splice Region (SNP) | VAF 68/407 reads (17%) | catalogued as rs1269935654; called by muse, mutect2, varscan2
- SOCS1 | c.184G>C p.A62P | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.681); catalogued as COSV59659669; called by muse, mutect2, varscan2
- SUPT5H | c.2638G>A p.G880R | Missense Mutation (SNP) | VAF 62/258 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.391); catalogued as COSV100781983; called by muse, mutect2, varscan2
- TDRD6 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 52/222 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.018); catalogued as rs766526554; called by muse, mutect2, varscan2
- TMEM168 | c.1933C>T p.R645C | Missense Mutation (SNP) | VAF 85/338 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as rs755373271, COSV57181281; called by muse, mutect2, varscan2
- ZC3H3 | c.325C>A p.H109N | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as rs183380208; called by muse, mutect2, varscan2
- ZCCHC2 | c.940-7C>T | Splice Region (SNP) | VAF 24/172 reads (14%) | catalogued as rs1476713813; called by muse, varscan2
- ZNF616 | c.1261C>T p.R421C | Missense Mutation (SNP) | VAF 67/326 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs750332191; called by muse, mutect2, varscan2
- ZNF618 | c.1510G>A p.A504T (on ENST00000374126 / NM_001318042.2; = p.A411T on NM_133374.2) | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs1212622535; called by muse, mutect2, varscan2
- ABCA12 | c.6506T>G p.L2169* (on ENST00000272895 / NM_173076.3; = p.L1851* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 49/298 reads (16%) | called by muse, mutect2, varscan2
- AFM | c.270+2T>G p.X90_splice | Splice Site (SNP) | VAF 27/165 reads (16%) | called by muse, mutect2, varscan2
- AKAP1 | c.1808A>C p.K603T | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ANGPT4 | c.242A>G p.K81R | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ANK2 | c.11290T>C p.S3764P | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARGLU1 | c.751_753del p.E251del | In Frame Del (DEL) | VAF 30/133 reads (23%) | called by pindel, varscan2
- ARPP21 | c.1996A>G p.R666G | Missense Mutation (SNP) | VAF 80/223 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ATG16L2 | c.1418A>C p.D473A | Missense Mutation (SNP) | VAF 39/255 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- BHLHE40 | c.858dup p.T287Hfs*11 | Frame Shift Ins (INS) | VAF 74/380 reads (19%) | called by mutect2, varscan2
- C6orf47 | c.423_427del p.G142Pfs*7 | Frame Shift Del (DEL) | VAF 38/328 reads (12%) | called by mutect2, pindel
- C9orf64 | c.174G>T p.R58S | Missense Mutation (SNP) | VAF 50/269 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- CACNA2D1 | c.518A>T p.Y173F | Missense Mutation (SNP) | VAF 74/326 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CNTNAP4 | c.2265T>A p.Y755* | Nonsense Mutation (SNP) | VAF 62/329 reads (19%) | called by muse, mutect2, varscan2
- DCTN4 | c.740A>G p.Q247R | Missense Mutation (SNP) | VAF 100/217 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DLG5 | c.2624G>T p.G875V | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.062); called by muse, mutect2
- EPHX1 | c.545G>C p.C182S | Missense Mutation (SNP) | VAF 57/347 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- FAM53C | c.853G>A p.V285I | Missense Mutation (SNP) | VAF 45/354 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- FKBP15 | c.3325G>A p.A1109T | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- FLACC1 | c.185A>T p.K62I | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); called by muse, mutect2
- GFI1 | c.1084C>T p.H362Y | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPATCH1 | c.740T>A p.L247Q | Missense Mutation (SNP) | VAF 42/300 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GRSF1 | c.1258-3T>G | Splice Region (SNP) | VAF 23/93 reads (25%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 24/101 reads (24%) | called by muse, varscan2
- IGHV3-23 | c.185del p.K62Rfs*22 | Frame Shift Del (DEL) | VAF 134/1107 reads (12%) | called by pindel, varscan2
- IGHV3-7 | c.314T>C p.L105P | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- IGHV3-7 | c.19T>C p.W7R | Missense Mutation (SNP) | VAF 81/183 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IL33 | c.795T>A p.F265L | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- IRAG1 | c.2216C>G p.S739* | Nonsense Mutation (SNP) | VAF 37/225 reads (16%) | called by muse, mutect2, varscan2
- KLHL28 | c.1093A>G p.T365A | Missense Mutation (SNP) | VAF 75/311 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- KNL1 | c.1373G>A p.S458N (on ENST00000346991 / NM_170589.5; = p.S432N on NM_144508.5) | Missense Mutation (SNP) | VAF 77/577 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- KPNA2 | c.213+2T>G p.X71_splice | Splice Site (SNP) | VAF 19/90 reads (21%) | called by muse, mutect2, varscan2
- LRRC10B | c.627C>G p.F209L | Missense Mutation (SNP) | VAF 50/408 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAGEA11 | c.233G>C p.R78T | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAGI1 | c.1720G>A p.A574T | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- MICAL2 | c.5263G>A p.A1755T | Missense Mutation (SNP) | VAF 54/348 reads (16%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MLH1 | c.2123T>C p.I708T | Missense Mutation (SNP) | VAF 165/435 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC2 | c.2797G>T p.D933Y | Missense Mutation (SNP) | VAF 41/265 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- NEXMIF | c.2024T>A p.L675Q | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- NSD1 | c.584A>C p.Y195S | Missense Mutation (SNP) | VAF 133/365 reads (36%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- OR13C4 | c.245T>G p.L82R | Missense Mutation (SNP) | VAF 37/239 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR1S2 | c.974T>C p.L325P | Missense Mutation (SNP) | VAF 227/602 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- PBX3 | c.881A>T p.K294M | Missense Mutation (SNP) | VAF 65/435 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PEDS1 | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- PIK3CB | c.9C>G p.F3L | Missense Mutation (SNP) | VAF 70/582 reads (12%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRUNE2 | c.5951C>G p.T1984R | Missense Mutation (SNP) | VAF 35/289 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- RABGAP1L | c.2440T>G p.Y814D | Missense Mutation (SNP) | VAF 65/318 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- RNF169 | c.1339C>T p.L447F | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SHOC1 | c.1367C>A p.S456Y | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- SLC22A3 | c.1454C>T p.P485L | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC35G6 | c.382G>C p.G128R | Missense Mutation (SNP) | VAF 38/247 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SLC37A4 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 38/328 reads (12%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- SLC6A11 | c.1840G>A p.A614T | Missense Mutation (SNP) | VAF 34/207 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC9C2 | c.1312T>C p.S438P | Missense Mutation (SNP) | VAF 57/260 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- SLF2 | c.3316T>C p.S1106P | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SMAD7 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAGAP | c.1775G>A p.S592N | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TLE5 | c.90A>T p.K30N | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TP73 | c.902A>C p.D301A | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- TRIP12 | c.1229G>A p.G410D | Missense Mutation (SNP) | VAF 55/294 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- WNT9A | c.337A>G p.S113G | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2
- YIPF5 | c.98G>C p.G33A | Missense Mutation (SNP) | VAF 67/431 reads (16%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF292 | c.3643A>T p.I1215L | Missense Mutation (SNP) | VAF 57/220 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF441 | c.602G>C p.C201S | Missense Mutation (SNP) | VAF 45/397 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- ZNF878 | c.868A>C p.K290Q | Missense Mutation (SNP) | VAF 45/287 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ZZEF1 | c.3916C>T p.P1306S | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ADAMTS10 | c.2277G>C p.G759= | Silent (SNP) | VAF 28/196 reads (14%) | called by muse, mutect2, varscan2
- ANK3 | c.7746G>A p.K2582= | Silent (SNP) | VAF 91/302 reads (30%) | called by muse, mutect2, varscan2
- ARHGEF10 | c.1764G>A p.R588= (on ENST00000398564; = p.R563= on NM_014629.4) | Silent (SNP) | VAF 11/94 reads (12%) | called by muse, mutect2, varscan2
- CCNT2 | c.615A>G p.K205= | Silent (SNP) | VAF 36/218 reads (17%) | called by muse, mutect2, varscan2
- CNNM1 | c.1470C>T p.D490= | Silent (SNP) | VAF 34/374 reads (9%) | catalogued as rs766825296; called by muse, mutect2
- CYP2U1 | c.723T>C p.F241= | Silent (SNP) | VAF 86/366 reads (23%) | called by muse, mutect2, varscan2
- FREM2 | c.3213A>C p.V1071= | Silent (SNP) | VAF 40/237 reads (17%) | called by muse, mutect2, varscan2
- FSIP2 | c.5853T>C p.A1951= | Silent (SNP) | VAF 53/198 reads (27%) | called by muse, mutect2, varscan2
- GALNT17 | c.1725C>T p.G575= | Silent (SNP) | VAF 27/147 reads (18%) | called by muse, mutect2, varscan2
- HES3 | c.237C>T p.L79= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs1200343551; called by muse, mutect2, varscan2
- HIF1AN | c.24T>A p.A8= | Silent (SNP) | VAF 46/159 reads (29%) | catalogued as rs1193348477; called by muse, mutect2, varscan2
- HOXB5 | c.460C>T p.L154= | Silent (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- IP6K2 | c.333A>C p.L111= | Silent (SNP) | VAF 98/696 reads (14%) | called by muse, mutect2, varscan2
- LCE3E | c.210C>A p.S70= | Silent (SNP) | VAF 19/109 reads (17%) | called by muse, mutect2, varscan2
- LRP1 | c.9456G>T p.V3152= | Silent (SNP) | VAF 22/126 reads (17%) | called by muse, mutect2, varscan2
- MYH1 | c.5401C>T p.L1801= | Silent (SNP) | VAF 36/179 reads (20%) | catalogued as COSV56852192; called by muse, mutect2, varscan2
- NRXN2 | c.63G>C p.A21= | Silent (SNP) | VAF 6/30 reads (20%) | called by muse, varscan2
- OAF | c.69G>A p.L23= | Silent (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- PLAGL2 | c.1410G>A p.G470= | Silent (SNP) | VAF 12/120 reads (10%) | catalogued as rs763545788; called by muse, mutect2, varscan2
- PPFIA3 | c.543G>A p.V181= | Silent (SNP) | VAF 13/76 reads (17%) | called by muse, mutect2, varscan2
- PPRC1 | c.2247G>A p.R749= | Silent (SNP) | VAF 31/164 reads (19%) | called by muse, mutect2, varscan2
- SLC6A4 | c.585G>A p.L195= | Silent (SNP) | VAF 22/93 reads (24%) | called by muse, mutect2, varscan2
- SRSF8 | c.729G>T p.R243= | Silent (SNP) | VAF 42/351 reads (12%) | called by muse, mutect2, varscan2
- TMEM79 | c.396T>A p.I132= | Silent (SNP) | VAF 57/334 reads (17%) | called by muse, mutect2, varscan2
- TXNDC11 | c.2085G>C p.V695= (on ENST00000356957 / NM_001303447.2; = p.V668= on NM_015914.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 36/207 reads (17%) | called by muse, mutect2, varscan2
- WDR62 | c.4092G>A p.R1364= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV54331461; called by muse, mutect2, varscan2
- ZNF516 | c.1293C>T p.A431= | Silent (SNP) | VAF 31/130 reads (24%) | catalogued as rs762139524, COSV71587656; called by muse, mutect2, varscan2
- ABL2 | c.*4224C>G | 3'UTR (SNP) | VAF 17/87 reads (20%) | called by muse, mutect2, varscan2
- AC120036.1 | n.104+6558G>C | Intron (SNP) | VAF 50/298 reads (17%) | called by muse, mutect2, varscan2
- ACVR1C | c.*398A>T | 3'UTR (SNP) | VAF 32/109 reads (29%) | called by muse, mutect2, varscan2
- AIRE | c.*331G>T | 3'UTR (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- ARHGAP19 | c.*1A>G | 3'UTR (SNP) | VAF 29/269 reads (11%) | called by muse, mutect2
- BACE1 | c.*3696T>C | 3'UTR (SNP) | VAF 51/266 reads (19%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021375 C>G | 5'Flank (SNP) | VAF 40/179 reads (22%) | called by muse, mutect2, varscan2
- BDP1 | c.4059+15G>T | Intron (SNP) | VAF 26/173 reads (15%) | catalogued as rs747885108; called by muse, mutect2, varscan2
- C16orf87 | c.-9G>A | 5'UTR (SNP) | VAF 16/236 reads (7%) | catalogued as rs777976461, COSV99587627; called by muse, mutect2
- CCDC126 | c.*1042G>A | 3'UTR (SNP) | VAF 14/70 reads (20%) | called by muse, mutect2, varscan2
- CCSER1 | c.2011-34089G>A | Intron (SNP) | VAF 14/104 reads (13%) | called by muse, mutect2
- CD27 | c.137-53A>G | Intron (SNP) | VAF 39/142 reads (27%) | called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.-220del | 5'UTR (DEL) | VAF 25/162 reads (15%) | called by mutect2, pindel, varscan2
- COL6A3 | c.*393T>C | 3'UTR (SNP) | VAF 22/75 reads (29%) | catalogued as rs1165908760; called by muse, mutect2, varscan2
- COMMD9 | chr11:36271374 T>A | 3'Flank (SNP) | VAF 41/239 reads (17%) | called by muse, mutect2, varscan2
- CPNE4 | c.*1298G>C | 3'UTR (SNP) | VAF 24/166 reads (14%) | called by muse, mutect2, varscan2
- CSMD1 | chr8:2938023 G>T | 3'Flank (SNP) | VAF 23/114 reads (20%) | catalogued as rs1187038857; called by muse, mutect2, varscan2
- CYP20A1 | c.*192G>A | 3'UTR (SNP) | VAF 14/113 reads (12%) | called by muse, mutect2, varscan2
- CYP2A6 | c.1161+169T>A | Intron (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- DLX6 | c.*456A>T | 3'UTR (SNP) | VAF 34/142 reads (24%) | called by muse, mutect2, varscan2
- DNAH5 | c.*422C>T | 3'UTR (SNP) | VAF 20/189 reads (11%) | called by muse, mutect2, varscan2
- DTNA | c.604-36C>T | Intron (SNP) | VAF 27/170 reads (16%) | called by muse, mutect2, varscan2
- DUOX2 | c.*1302G>A | 3'UTR (SNP) | VAF 9/113 reads (8%) | called by muse, mutect2
- DUSP8 | c.*485G>A | 3'UTR (SNP) | VAF 12/95 reads (13%) | catalogued as rs1348733229; called by muse, mutect2, varscan2
- E2F7 | c.*559C>T | 3'UTR (SNP) | VAF 14/82 reads (17%) | called by muse, mutect2, varscan2
- ENO2 | c.241-107C>T | Intron (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- ERCC6 | c.*1624T>C | 3'UTR (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- GGA2 | c.*3021G>C | 3'UTR (SNP) | VAF 11/79 reads (14%) | called by muse, mutect2, varscan2
- GGNBP2 | c.1641+21T>C | Intron (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2
- GULP1 | c.844-2184A>C | Intron (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- HMGA1 | c.*1333dup | 3'UTR (INS) | VAF 24/118 reads (20%) | catalogued as rs931062273; called by mutect2, varscan2
- HNRNPA3 | chr2:177220560 A>C | 3'Flank (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- HPGD | chr4:174522522 C>T | 5'Flank (SNP) | VAF 12/62 reads (19%) | catalogued as rs1040540365; called by muse, mutect2, varscan2
- HS3ST3A1 | c.-61C>T | 5'UTR (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2
- IGFN1 | c.1242-314G>C | Intron (SNP) | VAF 27/144 reads (19%) | called by muse, mutect2, varscan2
- ITPR2 | c.*1010del | 3'UTR (DEL) | VAF 28/119 reads (24%) | catalogued as rs895474441; called by mutect2, varscan2
- KCTD10 | c.*1815G>A | 3'UTR (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- KIAA1191 | c.*545G>A | 3'UTR (SNP) | VAF 14/142 reads (10%) | called by muse, mutect2, varscan2
- KLHL42 | c.*3433T>G | 3'UTR (SNP) | VAF 19/103 reads (18%) | called by muse, mutect2
- KTI12 | c.*159G>C | 3'UTR (SNP) | VAF 18/101 reads (18%) | called by muse, mutect2, varscan2
- LINC02693 | chr17:21528264 G>T | 3'Flank (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- MAPK8IP1 | c.*710G>T | 3'UTR (SNP) | VAF 27/191 reads (14%) | called by muse, mutect2, varscan2
- MIR7162 | chr10:30364745 G>A | 3'Flank (SNP) | VAF 8/43 reads (19%) | catalogued as rs1477220533; called by muse, varscan2
- MRTFB | c.1079+143A>G | Intron (SNP) | VAF 55/219 reads (25%) | called by muse, mutect2, varscan2
- MUC19 | n.20664-56C>A | Intron (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2, varscan2
- NADK2 | c.*14G>A | 3'UTR (SNP) | VAF 62/424 reads (15%) | called by muse, mutect2, varscan2
- NDUFS1 | c.*398G>A | 3'UTR (SNP) | VAF 23/130 reads (18%) | called by muse, mutect2, varscan2
- NECTIN1 | c.*3341G>T | 3'UTR (SNP) | VAF 19/152 reads (13%) | called by muse, mutect2, varscan2
- NEK10 | chr3:27110702 T>G | 3'Flank (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2
- NEURL1B | c.*4339A>G | 3'UTR (SNP) | VAF 23/178 reads (13%) | called by muse, mutect2, varscan2
- OPCML | c.*4371A>G | 3'UTR (SNP) | VAF 29/160 reads (18%) | called by muse, mutect2, varscan2
- PA2G4 | c.*309C>G | 3'UTR (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2
- PACRG | c.*285T>A | 3'UTR (SNP) | VAF 14/72 reads (19%) | called by muse, mutect2, varscan2
- PDE10A | c.*3287del | 3'UTR (DEL) | VAF 30/114 reads (26%) | called by mutect2, pindel, varscan2
- PLEKHD1 | c.*52G>A | 3'UTR (SNP) | VAF 21/64 reads (33%) | called by muse, mutect2, varscan2
- PLS3 | c.892-60C>T | Intron (SNP) | VAF 17/71 reads (24%) | called by muse, mutect2, varscan2
- PPFIA2 | c.303+78731G>T | Intron (SNP) | VAF 61/401 reads (15%) | called by muse, mutect2, varscan2
- PPM1A | c.952+173A>G | Intron (SNP) | VAF 17/115 reads (15%) | called by muse, mutect2, varscan2
- PPP4R3A | chr14:91510268 G>A | 5'Flank (SNP) | VAF 62/274 reads (23%) | catalogued as rs1384274643; called by muse, mutect2, varscan2
- PSG4 | c.*246A>T | 3'UTR (SNP) | VAF 28/140 reads (20%) | called by muse, mutect2, varscan2
- RAPGEF2 | c.*1041A>T | 3'UTR (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2, varscan2
- RBPMS | c.528+161C>T | Intron (SNP) | VAF 76/496 reads (15%) | called by muse, mutect2, varscan2
- RNF40 | c.*1850G>C | 3'UTR (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- RRN3 | c.*115G>A | 3'UTR (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- SACS | c.-11G>T | 5'UTR (SNP) | VAF 66/542 reads (12%) | called by muse, mutect2
- SCAI | c.*115G>T | 3'UTR (SNP) | VAF 12/124 reads (10%) | called by muse, mutect2, varscan2
- SCML1 | c.*898T>C | 3'UTR (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- SCN5A | c.*1194C>T | 3'UTR (SNP) | VAF 63/406 reads (16%) | called by muse, mutect2, varscan2
- SDCBP | c.-15-4059A>G | Intron (SNP) | VAF 30/127 reads (24%) | called by muse, mutect2, varscan2
- SIAH2 | c.-66C>G | 5'UTR (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- SLC1A3 | c.-95-100C>T | Intron (SNP) | VAF 24/114 reads (21%) | called by muse, mutect2, varscan2
- SLC26A2 | c.*3862G>A | 3'UTR (SNP) | VAF 20/113 reads (18%) | called by muse, mutect2, varscan2
- SLC35G3 | c.*389C>T | 3'UTR (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- SLC35G3 | c.*10T>C | 3'UTR (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- SPHKAP | c.*931A>G | 3'UTR (SNP) | VAF 25/113 reads (22%) | called by muse, mutect2, varscan2
- SRSF12 | c.*80C>T | 3'UTR (SNP) | VAF 17/137 reads (12%) | called by muse, mutect2, varscan2
- ST8SIA2 | c.*2113C>G | 3'UTR (SNP) | VAF 16/194 reads (8%) | called by muse, mutect2
- STEAP3 | c.*514A>T | 3'UTR (SNP) | VAF 24/125 reads (19%) | called by muse, mutect2, varscan2
- STMP1 | c.-35T>C | 5'UTR (SNP) | VAF 25/82 reads (30%) | called by muse, mutect2, varscan2
- SUSD6 | c.*3320T>G | 3'UTR (SNP) | VAF 28/157 reads (18%) | called by muse, mutect2, varscan2
- TAGAP | c.28-16A>C | Intron (SNP) | VAF 66/148 reads (45%) | called by muse, varscan2
- TMEM33 | c.*2308A>T | 3'UTR (SNP) | VAF 8/60 reads (13%) | catalogued as rs903974578; called by muse, varscan2
- TMEM50B | c.-42+944T>G | Intron (SNP) | VAF 51/334 reads (15%) | called by muse, mutect2, varscan2
- TMSB4X | c.-17+171A>C | Intron (SNP) | VAF 41/93 reads (44%) | called by muse, mutect2, varscan2
- TPM1 | c.240+4170G>A | Intron (SNP) | VAF 12/105 reads (11%) | called by muse, mutect2, varscan2
- TRAPPC2L | c.*1202G>A | 3'UTR (SNP) | VAF 50/305 reads (16%) | called by muse, mutect2, varscan2
- TRIAP1 | c.*26C>T | 3'UTR (SNP) | VAF 79/308 reads (26%) | catalogued as rs746454192, COSV56663760; called by muse, mutect2, varscan2
- TTYH3 | c.*709C>T | 3'UTR (SNP) | VAF 40/211 reads (19%) | catalogued as rs902740596, COSV51859159; called by muse, mutect2, varscan2
- VEPH1 | c.529+608A>C | Intron (SNP) | VAF 10/80 reads (13%) | called by muse, mutect2
- VPS35 | c.*569G>A | 3'UTR (SNP) | VAF 8/63 reads (13%) | called by muse, mutect2, varscan2
- VSIG10 | c.*339A>G | 3'UTR (SNP) | VAF 12/51 reads (24%) | called by muse, mutect2, varscan2
- WWC1 | c.*3077A>G | 3'UTR (SNP) | VAF 37/172 reads (22%) | called by muse, mutect2, varscan2
- XIRP2 | c.*1421G>T | 3'UTR (SNP) | VAF 57/416 reads (14%) | called by muse, mutect2, varscan2
- ZBED6 | c.*6724A>G | 3'UTR (SNP) | VAF 26/141 reads (18%) | called by muse, mutect2, varscan2
- ZMAT3 | c.*41G>A | 3'UTR (SNP) | VAF 17/91 reads (19%) | called by muse, mutect2, varscan2
- ZNF566 | chr19:36446682 T>C | 3'Flank (SNP) | VAF 43/300 reads (14%) | called by muse, mutect2, varscan2
- ZNF621 | c.*3009A>C | 3'UTR (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- ZSWIM4 | c.1180+1410G>C | Intron (SNP) | VAF 19/175 reads (11%) | called by muse, mutect2, varscan2
